National Lung Screening Trial (NLST) participant 107807 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 67 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 22): Negative screen, no significant abnormalities.
- T1 (day 355): Negative screen, no significant abnormalities.
- T2 (day 763): Negative screen, no significant abnormalities.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T4; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,510, study year T4. Site: lower lobe of lung (ICD-O-3 C34.3), determined from histology. Primary tumour location: left lower lobe. Histology: non-small cell carcinoma (ICD-O-3 8046/3). Cancer type as recorded on the NLST diagnostic evaluation form (the trial's best information on type): adenocarcinoma, NOS (ICD-O-3 8140). Grade: poorly differentiated (G3). Tumour size on pathology: 80 mm. AJCC 6th edition staging: stage IB (best stage, from pathologic TNM); clinical T2 N0 M0 (stage IB); pathologic T2 N0 M0 (stage IB). AJCC 7th edition staging: stage IIB; clinical T3 N0 M0; pathologic T3 N0 M0.

Follow-up
Last known free of lung cancer: day 1,435.
